Gene-level copy-number profile of tumor specimen TCGA-NA-A4QV-01A from TCGA case TCGA-NA-A4QV, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Basal cell carcinoma, NOS; Tissue or organ of origin: Corpus uteri; FIGO stage: Stage IB; Age at diagnosis: 72.2 years (26,379 days).
Specimen TCGA-NA-A4QV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.c24e71d6-0200-4851-abc9-1262335f2e07.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NA-A4QV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 821 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f17cbccc-d9fc-4064-b491-bcffdc3d813e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 72; copy number 1: 1,993; copy number 2: 16,713; copy number 3: 23,121; copy number 4: 12,243; copy number 5: 1,741; copy number 6: 2,424; copy number 7: 522; copy number 8: 338; copy number 9: 245; copy number 10: 41; copy number 11: 70; copy number 12: 18; copy number 13: 156; copy number 14: 23; copy number 15: 12; copy number 16: 19; copy number 17: 9; copy number 18: 13; copy number 19: 3; copy number 21: 9; copy number 23: 12; copy number 33: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NA-A4QV-01A-11D-A28Q-01): tumor purity 0.83, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 72 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,237,358–181,265,145, 2 genes: AC019235.1, LINC02500.
- chr15:30,254,402–32,461,809, 70 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,495 genes in 45 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,055,033–1,232,067, 16 genes, copy number 7 (within-gene range 4–7): AL645608.5, AL390719.1, AL645608.8, RNF223, C1orf159, AL390719.3, LINC01342, MIR200B, MIR200A, MIR429, AL390719.2, TTLL10-AS1, TTLL10, TNFRSF18, TNFRSF4, SDF4.
- chr2:46,580,937–47,176,511, 15 genes, copy number 7 (within-gene range 3–7): PIGF, CRIPT, AC020604.1, LINC01118, SOCS5, LINC01119, AC016722.1, AC016722.2, MCFD2, TTC7A, AC093732.2, AC093732.1, STPG4, AC073283.3, AC073283.1.
- chr2:54,456,317–64,341,647, 164 genes, copy number 7–9 (within-gene range 3–9) (broad region; genes not listed).
- chr3:13,476,982–13,880,071, 5 genes, copy number 7 (within-gene range 5–7): HDAC11-AS1, HDAC11, FBLN2, LINC00620, WNT7A.
- chr3:99,802,699–100,748,964, 17 genes, copy number 8: AC069222.1, CMSS1, FILIP1L, MIR3921, AC129803.1, TMEM30CP, DUSP12P1, VTI1BP1, TBC1D23, NIT2, TOMM70, LNP1, TMEM45A, ADGRG7, AC069223.1, GMFBP1, TFG.
- chr3:107,522,936–108,378,285, 9 genes, copy number 10 (within-gene range 6–10): BBX, LINC00636, LINC00635, AC012020.1, CD47, LINC01215, IFT57, HHLA2, HNRNPA1P17.
- chr4:52,252,820–54,298,245, 38 genes, copy number 7 (within-gene range 3–7): AC097522.2, AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1, RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA.
- chr6:11,414,636–11,515,710, 3 genes, copy number 7 (within-gene range 3–7): AL445430.2, AL445430.1, RNU1-64P.
- chr6:17,759,183–19,894,214, 24 genes, copy number 7–11: KIF13A, AL023807.1, NHLRC1, TPMT, KDM1B, DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1, AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1.
- chr6:27,737,000–29,487,956, 116 genes, copy number 7 (broad region; genes not listed).
- chr6:35,297,818–39,030,792, 94 genes, copy number 7–13 (within-gene range 2–13) (broad region; genes not listed).
- chr6:39,329,990–40,000,527, 10 genes, copy number 7: KIF6, AL136087.1, E2F4P1, RNU1-54P, DAAM2, AL592158.1, DAAM2-AS1, MOCS1, TUBBP9, FO393411.1.
- chr7:22,822,954–23,491,893, 21 genes, copy number 7: AC005682.2, SNHG26, SNORD93, AC005682.1, RPL12P10, FAM126A, KLHL7-DT, KLHL7, AK3P3, NUP42, AC005082.2, AC005082.1, GPNMB, MALSU1, IGF2BP3, AC021876.1, SNORD65C, RNU7-143P, AC079780.1, RPS2P32, Y_RNA.
- chr7:99,923,266–100,221,488, 30 genes, copy number 7 (within-gene range 4–7): GJC3, AC004522.3, Y_RNA, AC004522.1, AZGP1, AC004522.4, AZGP1P1, AC004522.2, AC004522.5, ZKSCAN1, ZSCAN21, ZNF3, COPS6, MCM7, MIR25, MIR93, MIR106B, AP4M1, TAF6, AC073842.2, CNPY4, MBLAC1, AC073842.1, RPL7P60, LAMTOR4, MAP11, MIR4658, GAL3ST4, GPC2, STAG3.
- chr10:44,712–3,047,083, 44 genes, copy number 8: AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1, LARP4B, AL359878.2, AL359878.1, GTPBP4, IDI2, IDI2-AS1, IDI1, WDR37, LINC00200, ADARB2, AL392083.2, AL392083.1, AL513304.1, ADARB2-AS1, AL355597.1, LINC00700, AL441943.1, MIR6072, RNU6-889P, AL441943.2, LINC02662, RNU6-576P, LINC00701, LINC02645, AL713851.2, AL713851.1, AL355361.1, AC026396.1, AL731533.1, AL731533.3.
- chr10:6,271,169–6,353,827, 1 gene, copy number 8 (within-gene range 4–8): LINC02649.
- chr10:6,350,316–7,118,469, 11 genes, copy number 8 (within-gene range 3–8): LINC02656, PRKCQ, PRKCQ-AS1, LINC02648, AL158210.1, LINP1, AL392086.2, LINC00706, LINC00707, AL392086.1, AL392086.3.
- chr10:13,156,684–17,454,595, 77 genes, copy number 9–19 (broad region; genes not listed).
- chr10:17,589,032–18,043,292, 11 genes, copy number 7–16: HACD1, AC069542.2, STAM-AS1, STAM, AC069542.1, TMEM236, MRC1, MIR511, AC069023.1, SLC39A12, SLC39A12-AS1.
- chr10:18,206,127–18,261,504, 1 gene, copy number 7 (within-gene range 2–7): AL390783.1.
- chr10:52,230,398–56,596,031, 28 genes, copy number 8–12: PRKG1-AS1, DKK1, RPL31P44, THAP12P3, LNCAROD, MBL2, Y_RNA, AC073174.1, LINC02672, SNRPEP8, AC036101.1, RNA5SP318, AL365496.1, PCDH15, RNU6-687P, AL353784.1, NEFMP1, MIR548F1, AC051618.1, AC016822.1, AL355314.1, AL355314.2, MTRNR2L5, GAPDHP21, AC069545.1, ZWINT, AC010996.1, AC025039.1.
- chr10:57,513,157–59,138,182, 17 genes, copy number 8–14 (within-gene range 3–14): AL731534.1, AC006484.1, MRPS35P3, AC026884.1, IPMK, TPT1P10, CISD1, AC016396.1, AC016396.2, UBE2D1, TFAM, BICC1, FAM133CP, RN7SKP196, LINC00844, RPLP1P10, TRAF6P1.
- chr10:60,778,331–63,658,521, 36 genes, copy number 8–33 (within-gene range 3–33): CDK1, RHOBTB1, RNU2-72P, LINC00845, TMEM26, TMEM26-AS1, AL356952.1, CABCOCO1, AL451049.1, LINC02625, ARID5B, RTKN2, LINC02621, AC024597.1, RN7SL591P, ZNF365, AC024598.1, AC067752.1, AC067751.1, ALDH7A1P4, ADO, EGR2, RNU6-543P, AL590502.1, NRBF2, JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1, REEP3, AC022387.2, MRPL35P2, AC022387.1.
- chr10:74,506,081–76,836,861, 42 genes, copy number 11–21: AC022540.1, MRPL35P3, Y_RNA, NDUFA8P1, POLR3DP1, FAM32CP, AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2, LRMDA, AC010997.6, MIR606, AL589863.2, AL589863.1, AL731568.1, RN7SL518P, RNU6-673P, AC012048.1, AC013286.1, AC024603.1, AC013738.1, ATP5MC1P8.
- chr10:78,696,062–79,445,624, 7 genes, copy number 16: AC016820.1, ZMIZ1-AS1, AL356753.1, ZMIZ1, PPIF, ZCCHC24, AL133481.1.
- chr11:49,817,778–50,422,316, 31 genes, copy number 10: AC130364.1, AC130364.2, TRIM51FP, AP006587.5, AP006587.6, AP006587.4, AP006587.3, TRIM51DP, AP006587.1, AP006587.2, OR4A1P, OR4A49P, OR4A18P, OR4A19P, OR4R3P, OR4C13, OR4C12, OR4C48P, OR4C45, OR4C49P, GTF2IP11, AC109635.3, AC109635.6, AC109635.5, PHKG1P3, AC109635.4, AC109635.2, AC109635.1, LINC02750, AC024405.2, AC024405.1.
- chr12:65,017,468–65,826,997, 15 genes, copy number 8 (within-gene range 6–8): AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52.
- chr12:68,674,371–70,920,738, 50 genes, copy number 8 (within-gene range 6–8): AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA.
- chr13:18,467,172–20,232,365, 67 genes, copy number 7 (broad region; genes not listed).
- chr13:76,990,660–77,327,094, 7 genes, copy number 13 (within-gene range 2–13): CLN5, AC001226.2, FBXL3, MYCBP2-AS1, AC001226.1, MYCBP2, MYCBP2-AS2.
- chr13:85,363,601–95,676,955, 104 genes, copy number 9–11 (broad region; genes not listed).
- chr13:95,692,538–95,695,705, 3 genes, copy number 9: MTND5P2, MTND6P18, MTCYBP3.
- chr14:101,068,283–101,457,117, 14 genes, copy number 8: MEG9, AL132709.7, AL132709.8, LINC02285, AL355836.2, U3, AL355836.4, AL355836.3, AL355836.1, AL359682.1, AL355096.1, LINC00524, LINC02314, AL049836.2.
- chr18:77,863,464–79,378,287, 22 genes, copy number 7: RNA5SP461, LINC01029, AC134978.1, RNU6-655P, AC107892.1, AC087399.1, AC012572.1, Y_RNA, AC044873.1, AC091027.2, AC091027.1, AC091027.3, LINC01896, SALL3, ATP9B, AC099689.3, AC125437.1, AC125437.2, AC125437.3, AC104423.1, AC023090.1, AC023090.2.
- chr19:29,083,094–31,787,255, 47 genes, copy number 7–18: AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P.
- chr19:36,334,453–36,605,276, 12 genes, copy number 15: ZFP14, AC092296.1, AC092296.4, ZFP82, AC092296.3, ZNF566, AC092295.2, CTBP2P7, ZNF260, AC092295.1, ZNF529, ZNF529-AS1.
- chr19:37,735,833–40,808,434, 158 genes, copy number 7–17 (within-gene range 2–17) (broad region; genes not listed).
- chr20:31,303,212–32,238,658, 49 genes, copy number 7: DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825.
- chr20:38,210,503–38,651,035, 27 genes, copy number 7: KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI, LBP, AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, AL035419.1.
- chr22:20,965,108–21,551,461, 47 genes, copy number 8: AIFM3, AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649, P2RX6P, LRRC74B, TUBA3GP, AC002472.4, BCRP2, AP000550.1, POM121L7P, E2F6P2, FAM230B, AP000550.2, FAM247A, GGT2, AP000550.3, E2F6P3, POM121L8P, BCRP6, FAM230H, AP000552.2, PPP1R26P5, LINC01651, FAM246A, AP000552.1, Metazoa_SRP, RIMBP3B, RN7SKP63, AP000552.3, Metazoa_SRP, HIC2, Metazoa_SRP, TMEM191C, PI4KAP2, AP000557.1, RN7SKP221, RIMBP3C.

Autosomal genes at a single copy (total copy number 1): 1,280. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
